MMRF case MMRF_1098 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7414ddf1-8e7f-4393-8a76-5bc122bdc4a4

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 49.8 years (18,175 days); ISS stage: II; Days to last known disease status: 1,748 days (4.8 years); Days to last follow up: 1,748 days (4.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 89 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 329 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -28 (ECOG 1): M Protein 2.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 44.2 mg/dL; Immunoglobulin G 18.8 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 4.4 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 8.1 g/dL; Glucose 4.9 mmol/L.
- Day 50 (ECOG 0): M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 8.35 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 0.94 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.98 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 4.51 mmol/L.
- Day 144 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.545 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.775 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.23 µg/mL; Hemoglobin 8.68 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 5.61 mmol/L.
- Day 260 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.883 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.896 mg/dL; Immunoglobulin G 5.3 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.77 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 9.67 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.
- Day 344 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.836 mg/dL; Immunoglobulin G 6.34 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.75 g/L; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 5.12 mmol/L.
- Day 414 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.954 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.965 mg/dL; Immunoglobulin G 6.68 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 6.16 mmol/L.
- Day 512 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 6.68 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 613 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.809 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.106 mg/dL; Immunoglobulin G 8.05 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 1.01 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 203 ×10⁹/L; Total Protein 6.4 g/dL.
- Day 704 (ECOG 0): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.102 mg/dL; Immunoglobulin G 8.91 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 1.18 g/L; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.68 mmol/L.
- Day 795 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 9.09 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 1.17 g/L; Beta 2 Microglobulin 1.77 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 9.8 mmol/L; Leukocytes 10.9 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 5.56 mmol/L.
- Day 890 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.792 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 9.02 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 1.1 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 5.12 mmol/L.
- Day 980 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.852 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 8.72 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 1.07 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.57 mmol/L.
- Day 1,068 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.894 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 9.08 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 1.37 g/L; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 1,173 (ECOG 1): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 8.86 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 1.19 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 1,285 (ECOG 1): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 8.91 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 1.03 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.27 mmol/L.
- Day 1,373 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.73 mg/dL; Immunoglobulin G 9.36 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.95 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 1,469 (ECOG 1): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 9.5 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.93 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.34 mmol/L.
- Day 1,560 (ECOG 1): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.59 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.93 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 1,685 (ECOG 1): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.97 mg/dL; Immunoglobulin G 9.66 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.88 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 1,748 (ECOG 1): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.02 mg/dL; Immunoglobulin G 9.66 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.88 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -28: Weight: 102 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1098_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -28 days.
- Sample MMRF_1098_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -28 days.
